Somatic mutation profile of tumor specimen ALCH-B0EA-TTP1-A (aliquot ALCH-B0EA-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0EA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Mucinous adenocarcinoma; Age at diagnosis: 75.8 years (27,686 days).
Specimen ALCH-B0EA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d38bbb8-2fd6-4599-8d28-ab4cbb5d1e06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EA-NB1-A (Blood Derived Normal), aliquot ALCH-B0EA-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aec75222-53af-47ab-b628-2d75625b129b

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, 3'UTR 2, Splice Site 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 56/349 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 43/383 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1057519999, COSV52661127, COSV52664176, COSV52966384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.1874C>A p.T625K | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV53994030; called by muse, mutect2, varscan2
- COL3A1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 38/377 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.316); catalogued as rs775677938, COSV58589378; called by muse, mutect2
- FANCA | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 30/700 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs374490484; called by muse, mutect2
- GTPBP4 | c.1463G>C p.R488P | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369802399; called by muse, mutect2
- KMT2B | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1299912616; called by muse, mutect2
- MGAT3 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); catalogued as COSV57864135; called by muse, mutect2, varscan2
- MIDN | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1362021177, COSV56295627; called by muse, mutect2
- NPR2 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 36/788 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61758531, CM156074; called by muse, mutect2
- SOCS6 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 38/377 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs374835963; called by muse, mutect2, varscan2
- SYCE1 | c.778C>T p.R260C (on ENST00000343131 / NM_001143764.3; = p.R224C on NM_130784.3) | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs143005509; called by muse, mutect2
- TMEM151A | c.54C>G p.D18E | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.115); catalogued as rs1363450806; called by muse, mutect2
- ACTL6B | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ALDH1L1 | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- COL28A1 | c.1015_1023del p.Q339_N341del | In Frame Del (DEL) | VAF 16/166 reads (10%) | called by mutect2, pindel
- DCST2 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ERBB3 | c.2203A>G p.I735V | Missense Mutation (SNP) | VAF 73/934 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- GIPR | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.113); called by muse, mutect2
- GPAT3 | c.894_910+8del p.X298_splice | Splice Site (DEL) | VAF 24/272 reads (9%) | called by mutect2, pindel
- ITFG1 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- LAMC1 | c.2725C>G p.P909A | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PTPRT | c.3694A>G p.I1232V | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- VEPH1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 26/630 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2
- ABCA10 | c.1795C>T p.L599= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as COSV52229165; called by muse, mutect2, varscan2
- CMYA5 | c.6540G>A p.S2180= | Silent (SNP) | VAF 28/276 reads (10%) | catalogued as rs781109063; called by muse, mutect2
- CSMD3 | c.1140C>A p.S380= | Silent (SNP) | VAF 54/628 reads (9%) | called by muse, mutect2
- MS4A6A | c.126C>T p.H42= | Silent (SNP) | VAF 36/287 reads (13%) | catalogued as rs113133013, COSV60617004; called by muse, mutect2, varscan2
- NUP133 | c.1338A>G p.A446= | Silent (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- PCDHA9 | c.1374C>T p.S458= | Silent (SNP) | VAF 32/652 reads (5%) | catalogued as rs782533558; called by muse, mutect2
- SKIDA1 | c.807C>T p.Y269= | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- GALNT17 | c.239-35160A>T | Intron (SNP) | VAF 11/191 reads (6%) | called by muse, mutect2
- KCNQ4 | c.*49G>A | 3'UTR (SNP) | VAF 20/154 reads (13%) | called by muse, mutect2
- MYO3A | c.*34C>T | 3'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as rs1486121081, COSV52154422; called by muse, mutect2
